Surgical pathology report (de-identified scan), TCGA case TCGA-AO-A129, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site MSKCC, specimen TCGA-AO-A129-01A (Primary Tumor).

[page 1 of 5]
Clinical Diagnosis & History:
Patient with left breast cancer IFDC on core left MRM and right prophylactic TM and SLNB.

- 1: SP: Left breast & axillary contents levels 1,2 with tags attached
- 2: SP: Right breast
- 3: SP: Level 3 axillary contents
- 4: SP: Sentinel node #1, level one right axilla
- 5: SP: Sentinel node #2, level one right axilla

- 1) BREAST, LEFT AND AXILLARY CONTENTS, LEVELS I AND II; EXCISION:
- INVASIVE DUCTAL CARCINOMA, WITH MEDULLARY FEATURES, HISTOLOGIC GRADE II/III (MODERATE TUBULE FORMATION), NUCLEAR GRADE III/III (MARKED VARIATION IN SIZE AND SHAPE), MEASURING 2.3 CM IN LARGEST DIMENSION MICROSCOPICALLY.
- DUCTAL CARCINOMA IN SITU (DCIS) IS ALSO IDENTIFIED, SOLID TYPE WITH HIGH NUCLEAR GRADE AND EXTENSIVE NECROSIS.
- THE DCIS CONSTITUTES <= 25% OF THE TOTAL TUMOR MASS, AND IS PRESENT ADMIXED WITH THE INVASIVE COMPONENT
- THE INVASIVE CARCINOMA IS LOCATED IN THE LOWER OUTER QUADRANT. THE DCIS IS LOCATED IN THE LOWER OUTER QUADRANT.
- NO INVOLVEMENT OF THE NIPPLE BY EITHER IN SITU OR INVASIVE CARCINOMA IS IDENTIFIED.
- NO CALCIFICATIONS ARE IDENTIFIED IN EITHER THE INVASIVE OR IN SITU CARCINOMA.
- NO VASCULAR INVASION IS NOTED.
- NO INVOLVEMENT OF THE SURGICAL MARGINS BY EITHER INVASIVE OR IN SITU CARCINOMA IS IDENTIFIED.
- NO SKIN INVOLVEMENT BY CARCINOMA IS IDENTIFIED.
- THE NON-NEOPLASTIC BREAST TISSUE IS UNREMARKABLE.
- THE LYMPH NODE STATUS IS AS FOLLOWS (EXPRESSED AS THE NUMBER OF POSITIVE LYMPH NODES IN RELATION TO THE TOTAL NUMBER OF LYMPH NODES EXAMINED): LEVEL I: 2/13; LEVEL II: 0/4.
- THERE IS EXTRANODAL EXTENSION OF CARCINOMA.
- RESULTS OF SPECIAL STAINS (ER, PR, HER2-NEU) WILL BE REPORTED AS AN ADDENDUM.

** Continued on next page **

100-0-3
carcinoma, infiltrating duct, nos 8504/3
Site: breast, nos 850.9 lw 10/22/41

UUUD: DD973A0E-3C33-4ED7-BF2C-7E5E3C55032B

Street	No.
Chicago Ave. N. W. corner	12
Chicago Ave. N. W. corner	14
Chicago Ave. N. W. corner	16
Chicago Ave. N. W. corner	18
Chicago Ave. N. W. corner	20
Chicago Ave. N. W. corner	22
Chicago Ave. N. W. corner	24
Chicago Ave. N. W. corner	26
Chicago Ave. N. W. corner	28
Chicago Ave. N. W. corner	30
Chicago Ave. N. W. corner	32
Chicago Ave. N. W. corner	34
Chicago Ave. N. W. corner	36
Chicago Ave. N. W. corner	38
Chicago Ave. N. W. corner	40
Chicago Ave. N. W. corner	42
Chicago Ave. N. W. corner	44
Chicago Ave. N. W. corner	46
Chicago Ave. N. W. corner	48
Chicago Ave. N. W. corner	50
Chicago Ave. N. W. corner	52
Chicago Ave. N. W. corner	54
Chicago Ave. N. W. corner	56
Chicago Ave. N. W. corner	58
Chicago Ave. N. W. corner	60
Chicago Ave. N. W. corner	62
Chicago Ave. N. W. corner	64
Chicago Ave. N. W. corner	66
Chicago Ave. N. W. corner	68
Chicago Ave. N. W. corner	70
Chicago Ave. N. W. corner	72
Chicago Ave. N. W. corner	74
Chicago Ave. N. W. corner	76
Chicago Ave. N. W. corner	78
Chicago Ave. N. W. corner	80
Chicago Ave. N. W. corner	82
Chicago Ave. N. W. corner	84
Chicago Ave. N. W. corner	86
Chicago Ave. N. W. corner	88
Chicago Ave. N. W. corner	90
Chicago Ave. N. W. corner	92
Chicago Ave. N. W. corner	94
Chicago Ave. N. W. corner	96
Chicago Ave. N. W. corner	98
Chicago Ave. N. W. corner	100

[page 2 of 5]
- 2) BREAST, RIGHT; EXCISION:
- BENIGN BREAST PARENCHYMA WITH SECRETORY CHANGE.
- 3) LYMPH NODES, LEFT AXILLA, LEVEL III; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).
- 4) LYMPH NODES, SENTINEL #1, LEVEL I, RIGHT AXILLA; EXCISION:
- TWO BENIGN LYMPH NODES (0/2). DEEPER LEVEL RECUTS AND SPECIAL STAINS HAVE BEEN ORDERED. THE RESULTS WILL BE REPORTED IN AN ADDENDUM.
- 5) LYMPH NODE, SENTINEL #2, LEVEL I, RIGHT AXILLA; EXCISION:
- BENIGN BREAST TISSUE. NO LYMPH NODE IDENTIFIED.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
	HER2-C	
	ER-C	
	PR-C	
	NEG CONT	
	IMM RECUT	
	NEG-HER2	
	AE1:AE3	
	CAM 5.2	
	AE1:AE3	
	CAM 5.2	
	NEG CONT	
	IMM RECUT	
	NEG CONT	
	IMM RECUT	

Gross Description:

- 1) The specimen is received fresh, labeled, "Left breast & axillary contents levels 1,2 with tags attached". It is a product of left modified mastectomy, consisting of an ellipse of tan skin, breast tissue and axillary tail designated as levels one and two. The skin measures 15.0 x 4.0 cm. The breast tissue measures 23.0 x 23.0 x 6.5 cm. The axillary tail site measures 14.0 x 6.5 x 2.0 cm. The nipple is everted. No visible scars are present on the skin surface. A scanty amount of skeletal muscle tissue is present at the deep margin which is inked. The breast tissue was sectioned to reveal an ill-defined pink-gray focally hemorrhagic rubbery tumor completely surrounded by thickened fibrous tissue situated in the lower outer quadrant, 3.5 cm from the deep surgical margin. The fibrous tissue surrounding the tumor abuts the deep surgical margin. The rest of the tissue is predominantly fibrous. Serial sectioning of the axillary tail reveals

PATH
REPORT

** Continued on next page **

[page 3 of 5]
----- Page 3 of 5
multiple lymph nodes, ranging from 0.3 up to 1.5 cm in greatest dimension.
Representative sections were submitted, portion of the tumor was given to
TPS.

Summary of Sections:

N nipple
T tumor
DM deep margin closest to the tumor
UOQ upper outer quadrant
LOQ lower outer quadrant
LIQ lower inner quadrant
LN1 lymph nodes level one
LN2 lymph nodes level two

2) The specimen is received fresh, labeled, "Right breast, (stitch marks axillary tail)". It is a product of right modified mastectomy consisting of an ellipse of tan skin with breast tissue. The skin measures 15.5 x 5.0 cm. The breast tissue measures 16.0 x 16.0 x 6.0 cm. The nipple is everted. Grossly no visible scars are present on the skin surface. There is a scanty amount of skeletal muscle tissue present at the deep margin which is inked. The breast tissue was sectioned to reveal fibrofatty tissue. The fibrous tissue counts to approximately 55% of the entire breast tissue. Grossly no evert lesions were identified. No lymph nodes were present at the axillary tail site. Representative sections were submitted.

Summary of Sections:

N nipple
OUQ upper outer quadrant
LOW lower outer quadrant
UIQ upper inner quadrant
LIQ lower inner quadrant
DM deep margin
AXT axillary tail site

3) The specimen is received in formalin, labeled, "Level 3 axillary contents". It consists of three piece of fibroadipose tissue measuring in aggregate 1.5 x 1.0 x 0.6 cm. Entirely submitted.

Summary of Sections:

U undesignated

4) The specimen is received in formalin, labeled, "Sentinel node #1, level one, right axilla". It consists of a single piece of adipose tissue measuring 2.5 x 2.0 x 0.5 cm. Entirely submitted.

Summary of Sections:

U undesignated

PATH
REPORT

** Continued on next page **

[page 4 of 5]
5) The specimen is received in formalin, labeled, "Sentinel node #2, level one right axilla". It consists of a single piece of fibroadipose tissue with embedded lymph node, measuring 0.8 cm in its greatest dimension. Entirely submitted.

Summary of Sections:
LN lymph node

Summary of Sections:

Part 1: SP: Left breast & axillary contents levels 1,2 with tags attached

Block	Sect. Site	PCs
5	ALN	13
2	BLN	7
1	DM	3
2	LIQ	2
2	LOQ	2
2	N	2
4	T	4
2	UIQ	2
2	UOQ	2

Part 2: SP: Right breast

Block	Sect. Site	PCs
1	AXT	2
1	DM	3
4	LIQ	4
4	LOQ	4
2	N	2
4	UIQ	4
4	UOQ	4

Part 3: SP: Level 3 axillary contents

Block	Sect. Site	PCs
1	U	3

Part 4: SP: Sentinel node #1, level one right axilla

Block	Sect. Site	PCs
2	U	2

Part 5: SP: Sentinel node #2, level one right axilla

Block	Sect. Site	PCs
1	LN	1

PATH
REPORT

** Continued on next page **

[page 5 of 5]
Procedures/Addenda:

Addendum

Date Ordered:

Date Complete

Date Reported:

Status: Signed Out

By:

Addendum Diagnosis

ADDENDUM

SITE: LEFT BREAST

- ER-ICA: NEGATIVE
- PR-ICA: NEGATIVE
- HER2/NEU (HERCEPT): NEGATIVE (STAINING INTENSITY OF 0).
- CONTROLS ARE SATISFACTORY.

Addendum

Date Ordered:

Date Complete:

Date Reported:

Status: Signed Out

By:

Addendum Diagnosis

ADDENDUM

SITE: SENTINEL LYMPH NODE, RIGHT AXILLA
PART #4.

ADDITIONAL H&E STAINED SECTIONS AND IMMUNOHISTOCHEMICAL STAINS FOR
CYTOKERATINS (AE1:AE3 AND CAM 5.2) SHOW NO EVIDENCE OF METASTATIC TUMOR.

PATH
REPORT

** End of Report **

Source: NCI Genomic Data Commons file 45387440-7ca7-4be3-bf40-5a50f619965c (TCGA-AO-A129.DD973A0E-3CC3-4ED7-BE2C-7E5E3C55032B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).